Somatic mutation profile of tumor specimen C3L-03969-03 (aliquot CPT0229360007) from CPTAC case C3L-03969, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 76.9 years (28,101 days).
Specimen C3L-03969-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f265e83-e35e-4b0d-a482-04f9a6b7b790.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03969-31 (Blood Derived Normal), aliquot CPT0229500002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4a1cded-af05-40d5-b7e7-a4b66eaab7fe

The open-access MAF lists 395 somatic variants for this specimen: 280 protein-altering or splice-affecting, 68 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 251, Silent 68, Intron 22, Nonsense Mutation 18, RNA 8, Splice Site 7, 3'UTR 5, 5'Flank 5, 3'Flank 4, 5'UTR 3, Splice Region 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.5610-2A>G p.X1870_splice (on ENST00000358273 / NM_001042492.3; = p.X1849_splice on NM_000267.3) | Splice Site (SNP) | VAF 34/268 reads (13%) | catalogued as rs1135402876, CS153443, CS165117; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 36/384 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- AC053503.6 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.063); catalogued as rs1370644707; called by muse, mutect2
- ACKR1 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.325); catalogued as rs1357930716; called by muse, mutect2
- ANK2 | c.2932G>C p.G978R | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52170263; called by muse, mutect2
- ARHGAP4 | c.1324A>C p.T442P | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV63134170; called by muse, mutect2
- ARMC5 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 31/393 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.076); catalogued as rs1473236430, COSV51659676; called by muse, mutect2
- BAHCC1 | c.2768C>T p.S923L | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs901395687; called by muse, mutect2
- C6orf15 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs867362055, COSV52539139; called by muse, mutect2
- CACNA1H | c.7016C>T p.P2339L | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs920993190; called by muse, mutect2
- CALR | c.783G>T p.W261C | Missense Mutation (SNP) | VAF 32/556 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100331159; called by muse, mutect2
- CCT8L2 | c.100C>A p.L34M | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100742755; called by muse, mutect2
- COL24A1 | c.1019A>G p.E340G | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs753861926; called by muse, mutect2
- CR1 | c.5449G>A p.G1817R | Missense Mutation (SNP) | VAF 38/377 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549640201, COSV65456959; called by muse, mutect2, varscan2
- CREB3L1 | c.1373C>A p.P458Q | Missense Mutation (SNP) | VAF 13/313 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.237); catalogued as COSV55830219; called by muse, mutect2
- CROCC | c.1007A>T p.Q336L | Missense Mutation (SNP) | VAF 21/353 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV65013362; called by muse, mutect2
- CYLC1 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs1398576229, COSV61412907, COSV61415034; called by muse, mutect2, varscan2
- CYP2A13 | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 28/317 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs532858701; called by muse, mutect2
- DCDC1 | c.3633G>T p.W1211C (on ENST00000597505 / NM_001367979.1; = p.W318C on NM_020869.3) | Missense Mutation (SNP) | VAF 21/347 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100337764, COSV60309803; called by muse, mutect2
- DDX60 | c.5039G>T p.S1680I | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV67099177; called by muse, mutect2
- DIDO1 | c.5372G>T p.G1791V | Missense Mutation (SNP) | VAF 24/337 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56613246; called by muse, mutect2
- DNAH2 | c.12778C>T p.R4260C | Missense Mutation (SNP) | VAF 14/378 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66726973; called by muse, mutect2
- DUOX2 | c.1525G>T p.V509L | Missense Mutation (SNP) | VAF 22/457 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1300952424; called by muse, mutect2
- FAM124B | c.461G>T p.R154I | Missense Mutation (SNP) | VAF 45/363 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV66271390, COSV66271900; called by muse, mutect2, varscan2
- GABRB3 | c.350G>T p.W117L | Missense Mutation (SNP) | VAF 14/456 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54685545; called by muse, mutect2
- GAS2L3 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 23/286 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV57157881; called by muse, mutect2
- GP2 | c.686G>T p.C229F (on ENST00000381362 / NM_001007240.3; = p.C226F on NM_001502.4) | Missense Mutation (SNP) | VAF 23/365 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100221544; called by muse, mutect2
- GP6 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 22/546 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as rs1274065849; called by muse, mutect2
- GPR50 | c.543C>G p.N181K | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.316); catalogued as COSV99505610; called by muse, mutect2, varscan2
- HCN1 | c.2099C>A p.T700N | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.1); catalogued as rs1352995652, COSV100301137; called by muse, mutect2
- HOXA3 | c.268C>A p.L90M | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.459); catalogued as rs769654378; called by muse, mutect2, varscan2
- HR | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 33/335 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV57195507; called by muse, mutect2
- HTR1F | c.170C>A p.P57Q | Missense Mutation (SNP) | VAF 35/452 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60389264; called by muse, mutect2
- ICE1 | c.5047C>T p.P1683S | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV56831702; called by muse, mutect2
- ISG20L2 | c.71A>G p.K24R | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs1162927086; called by muse, mutect2
- ITGB6 | c.554T>C p.F185S | Missense Mutation (SNP) | VAF 13/288 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1050990851; called by muse, mutect2
- KCNT2 | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54062032; called by muse, mutect2
- KDM6B | c.440T>C p.I147T | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as rs1259313427; called by muse, mutect2
- KIF2B | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV52129639; called by muse, mutect2
- KLHL1 | c.1628G>T p.R543I | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100918305; called by muse, mutect2
- KRTAP27-1 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV67001192; called by muse, mutect2
- LHFPL3 | c.89C>A p.T30N | Missense Mutation (SNP) | VAF 51/565 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757509847, COSV67811903; called by muse, mutect2
- MACF1 | c.1934A>T p.K645M | Missense Mutation (SNP) | VAF 15/169 reads (9%) | catalogued as rs1218152543, COSV58385734; called by muse, mutect2
- MAD1L1 | c.1967C>A p.A656D | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1201226915, COSV99767683; called by muse, mutect2
- MYH3 | c.2833G>A p.E945K | Missense Mutation (SNP) | VAF 36/620 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1478996807; called by muse, mutect2
- NEU4 | c.808C>G p.P270A (on ENST00000391969 / NM_001167602.3; = p.P282A on NM_080741.4) | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57989811; called by muse, mutect2
- NRG3 | c.980G>T p.R327L | Missense Mutation (SNP) | VAF 10/255 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64545807, COSV64552578, COSV64583332; called by muse, mutect2
- NRXN1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 15/256 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.2); catalogued as rs796052775, COSV68014124; ClinVar: uncertain significance; called by muse, mutect2
- OR1A1 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58403187; called by muse, mutect2, varscan2
- OR7G3 | c.507C>A p.C169* | Nonsense Mutation (SNP) | VAF 24/300 reads (8%) | catalogued as rs149823005, COSV59640430; called by muse, mutect2
- P2RY14 | c.337G>T p.G113W | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56386987; called by muse, mutect2
- PCDH15 | c.4919G>T p.R1640M | Missense Mutation (SNP) | VAF 49/714 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV57414409; called by muse, mutect2
- PCDHA7 | c.2203G>T p.V735L | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs144694616; called by muse, mutect2
- PDE4A | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 24/429 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.056); catalogued as COSV100764271; called by muse, mutect2
- PGK2 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV59164420; called by muse, mutect2
- PKD1 | c.8536A>T p.T2846S | Missense Mutation (SNP) | VAF 83/1116 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.904); catalogued as CM164775, COSV51927098; called by muse, mutect2
- PKHD1 | c.8225G>T p.W2742L | Missense Mutation (SNP) | VAF 17/540 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs1562410271; called by muse, mutect2
- PLA2R1 | c.2974G>T p.A992S | Missense Mutation (SNP) | VAF 13/199 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV99322171; called by muse, mutect2
- POT1 | c.1295G>C p.R432P | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62928536; called by muse, mutect2, varscan2
- POTEE | c.2336G>T p.W779L | Missense Mutation (SNP) | VAF 22/803 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100388884; called by muse, mutect2
- PRKAR2A | c.865A>G p.I289V | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as rs1030263167; called by muse, mutect2, varscan2
- PRPF4B | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as COSV100527942; called by muse, mutect2
- RAB3C | c.674G>C p.C225S | Missense Mutation (SNP) | VAF 4/77 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1386964219; called by muse, mutect2
- RARS2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 34/557 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs760114539, COSV99055575; ClinVar: uncertain significance; called by muse, mutect2
- RYR2 | c.739G>C p.V247L | Missense Mutation (SNP) | VAF 40/446 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as COSV63708405; called by muse, mutect2
- RYR2 | c.12538G>T p.G4180C | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV63699981; called by muse, mutect2, varscan2
- RYR3 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66805410; called by muse, mutect2
- SEZ6 | c.2803G>T p.V935L | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs992255987; called by muse, mutect2
- SFI1 | c.1316C>T p.P439L (on ENST00000400288 / NM_001007467.3; = p.P408L on NM_014775.4) | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101192122, COSV66292484; called by muse, mutect2
- SIRPG | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 36/301 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53808942; called by muse, mutect2, varscan2
- SLC34A2 | c.1008G>A p.W336* | Nonsense Mutation (SNP) | VAF 18/585 reads (3%) | catalogued as COSV65941840; called by muse, mutect2
- SLIT1 | c.4172G>A p.C1391Y | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1430831311; called by muse, mutect2, varscan2
- SLITRK2 | c.1003C>A p.P335T | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59424132, COSV59425784; called by muse, mutect2
- SLITRK2 | c.1004C>G p.P335R | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100157301; called by muse, mutect2
- SMAD2 | c.1280+1G>T p.X427_splice | Splice Site (SNP) | VAF 14/165 reads (8%) | catalogued as COSV50993477; called by muse, mutect2
- SNRPN | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100578899, COSV57595118; called by muse, mutect2
- SPEF2 | c.4628C>T p.S1543L | Missense Mutation (SNP) | VAF 11/255 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV57429547; called by muse, mutect2
- SPTA1 | c.5377C>T p.R1793W | Missense Mutation (SNP) | VAF 46/672 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375618954; called by muse, mutect2
- SYT4 | c.700C>A p.Q234K | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV99673542; called by muse, mutect2
- TCF20 | c.395G>A p.S132N | Missense Mutation (SNP) | VAF 21/247 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs1398922922; called by muse, mutect2
- TG | c.3074G>A p.G1025D | Missense Mutation (SNP) | VAF 35/643 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs764171548; called by muse, mutect2
- TMEM132A | c.1468G>C p.V490L (on ENST00000453848 / NM_178031.3; = p.V491L on NM_017870.4) | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV50008852; called by muse, mutect2
- TPSD1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 38/622 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.506); catalogued as rs370368331, COSV52974267; called by muse, mutect2
- TRPC4 | c.928C>A p.L310M | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58990132; called by muse, mutect2
- TSSK4 | c.409G>C p.A137P | Missense Mutation (SNP) | VAF 13/221 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.884); catalogued as COSV99841620; called by muse, mutect2
- UNC80 | c.1682C>A p.T561N | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV55897096; called by muse, mutect2, varscan2
- USH2A | c.9874C>A p.Q3292K | Missense Mutation (SNP) | VAF 24/559 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as CM149928, COSV56328200, COSV56438733; called by muse, mutect2
- USH2A | c.8284C>T p.P2762S | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as CM148280, COSV56326513, COSV56435934; called by muse, mutect2
- VWA5B1 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99232806; called by muse, mutect2
- ZC2HC1B | c.410C>G p.T137S | Missense Mutation (SNP) | VAF 8/217 reads (4%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1347741446; called by muse, mutect2
- ZNF479 | c.1411G>T p.G471C | Missense Mutation (SNP) | VAF 46/381 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100482846, COSV58636035; called by muse, mutect2, varscan2
- ZNF544 | c.1335C>G p.F445L | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs374475436, COSV54136697; called by muse, mutect2, varscan2
- ZNF800 | c.1433C>A p.S478* | Nonsense Mutation (SNP) | VAF 17/216 reads (8%) | catalogued as COSV56180077; called by muse, mutect2
- ABCB5 | c.1742A>T p.H581L (on ENST00000404938 / NM_001163941.2; = p.H136L on NM_178559.6) | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- ACSL6 | c.1129-1G>T p.X377_splice (on ENST00000379240; = p.X402_splice on NM_015256.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 22/200 reads (11%) | called by muse, mutect2, varscan2
- ADAMTS17 | c.1031+1G>T p.X344_splice | Splice Site (SNP) | VAF 14/273 reads (5%) | called by muse, mutect2
- ADAMTS18 | c.2957G>T p.C986F | Missense Mutation (SNP) | VAF 15/385 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRD2 | c.1666C>A p.H556N | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT tolerated (1); PolyPhen possibly damaging (0.855); called by muse, mutect2
- ALPI | c.821A>T p.Q274L | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- ARPC2 | c.796A>G p.M266V | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2
- ASAH2 | c.1075G>T p.G359* | Nonsense Mutation (SNP) | VAF 24/476 reads (5%) | called by muse, mutect2
- ATG7 | c.1930G>C p.D644H | Missense Mutation (SNP) | VAF 11/396 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- BOD1L1 | c.689G>C p.S230T | Missense Mutation (SNP) | VAF 18/492 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2
- CAAP1 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 12/302 reads (4%) | called by muse, mutect2
- CASP9 | c.278G>T p.R93M | Missense Mutation (SNP) | VAF 28/576 reads (5%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.497); called by muse, mutect2
- CASS4 | c.2096C>A p.P699H | Missense Mutation (SNP) | VAF 42/407 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CBFA2T3 | c.1859C>A p.S620Y | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2
- CCNT2 | c.869A>G p.D290G | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.351); called by muse, mutect2
- CDC16 | c.681G>T p.L227F | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); called by muse, mutect2
- CDH4 | c.1615C>A p.Q539K | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2
- CFAP54 | c.8444G>T p.S2815I | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.196); called by muse, mutect2
- CHRNA9 | c.563C>A p.A188D | Missense Mutation (SNP) | VAF 12/365 reads (3%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.67); called by muse, mutect2
- CNTN2 | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 12/355 reads (3%) | called by muse, mutect2
- CNTNAP4 | c.890C>A p.A297E | Missense Mutation (SNP) | VAF 14/396 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2
- COL6A5 | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); called by muse, mutect2
- CRB1 | c.3050G>C p.S1017T | Missense Mutation (SNP) | VAF 19/282 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.393); called by muse, mutect2
- CRLF2 | c.582T>A p.Y194* | Nonsense Mutation (SNP) | VAF 18/400 reads (5%) | called by muse, mutect2
- CSMD3 | c.10655T>A p.L3552Q (on ENST00000297405 / NM_001363185.1; = p.L3383Q on NM_052900.3) | Missense Mutation (SNP) | VAF 13/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CSMD3 | c.6361G>T p.V2121L (on ENST00000297405 / NM_001363185.1; = p.V2017L on NM_052900.3) | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- CYP4Z1 | c.579G>T p.K193N | Missense Mutation (SNP) | VAF 22/263 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- DCDC1 | c.2201C>A p.T734K | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- DGCR8 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- DIDO1 | c.597G>T p.E199D | Missense Mutation (SNP) | VAF 29/361 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- DLGAP2 | c.2579G>T p.R860M | Missense Mutation (SNP) | VAF 13/287 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- DNAH9 | c.13036C>G p.L4346V | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DNAJC27 | c.653G>T p.S218I | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2
- DPYD | c.1855G>T p.A619S | Missense Mutation (SNP) | VAF 18/415 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.387); called by muse, mutect2
- DPYS | c.1068G>A p.M356I | Missense Mutation (SNP) | VAF 20/510 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2
- DRD2 | c.587T>A p.V196D | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DRD5 | c.1274T>A p.V425E | Missense Mutation (SNP) | VAF 10/332 reads (3%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- DYNC1H1 | c.5753C>T p.A1918V | Missense Mutation (SNP) | VAF 30/440 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ELN | c.992C>A p.P331Q | Missense Mutation (SNP) | VAF 26/759 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.622); called by muse, mutect2
- EPHA6 | c.1979C>A p.T660N (on ENST00000389672 / NM_001080448.3; = p.T52N on NM_173655.4) | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- ERICH3 | c.2034A>T p.Q678H | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2
- FAM47B | c.1011C>A p.N337K | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.98); PolyPhen benign (0.005); called by muse, mutect2
- FMO4 | c.681G>T p.W227C | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- FNDC1 | c.928T>A p.W310R | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FOXS1 | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 19/376 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- FUT8 | c.496G>T p.D166Y (on ENST00000360689 / NM_001371534.1; = p.D3Y on NM_004480.4) | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FXYD6 | c.49C>A p.L17M | Missense Mutation (SNP) | VAF 23/324 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); called by muse, mutect2
- GABRB1 | c.94A>G p.S32G | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- GABRB3 | c.351G>T p.W117C | Missense Mutation (SNP) | VAF 14/459 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GADL1 | c.479T>A p.L160Q | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GFOD1 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 21/338 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GLDC | c.2921C>A p.P974H | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2
- GRIA1 | c.1316G>T p.C439F | Missense Mutation (SNP) | VAF 36/444 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- GRIK5 | c.70C>A p.L24M | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); called by muse, mutect2
- GRPR | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.042); called by mutect2, varscan2
- GSTP1 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2
- GUCY1A2 | c.1717T>A p.C573S | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- GYS2 | c.358A>T p.I120L | Missense Mutation (SNP) | VAF 19/242 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.398); called by muse, mutect2
- HAP1 | c.604A>T p.R202W | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HDAC9 | c.1366C>A p.Q456K | Missense Mutation (SNP) | VAF 23/456 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2
- HERC1 | c.3844T>A p.C1282S | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- HLF | c.845A>T p.K282M | Missense Mutation (SNP) | VAF 12/355 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2
- HOXD4 | c.326G>C p.G109A | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2
- HSF4 | c.385G>T p.G129C | Missense Mutation (SNP) | VAF 28/464 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.648); called by muse, mutect2
- IFFO2 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 17/384 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2
- IFI35 | c.293A>G p.K98R | Missense Mutation (SNP) | VAF 46/280 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 20/476 reads (4%) | called by muse, mutect2
- IGLL5 | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 78/986 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.752); called by muse, mutect2
- JADE1 | c.2315A>C p.Q772P | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNA5 | c.1532C>A p.P511H | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNB1 | c.1918G>A p.A640T | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2
- KCNJ10 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 19/393 reads (5%) | called by muse, mutect2
- KIAA1586 | c.2063C>T p.T688I | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- KIF13B | c.3382G>A p.A1128T | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.312); called by muse, mutect2
- KIF19 | c.1619G>T p.R540L | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2
- KIRREL2 | c.625C>A p.Q209K | Missense Mutation (SNP) | VAF 10/314 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.136); called by muse, mutect2
- KIZ | c.1795G>T p.G599C | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KLF17 | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.034); called by muse, mutect2
- KRT83 | c.182C>A p.A61D | Missense Mutation (SNP) | VAF 68/674 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.13); called by muse, mutect2
- KSR2 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 9/159 reads (6%) | called by muse, mutect2
- LAMB4 | c.3692T>C p.L1231S | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- LDLR | c.1253A>G p.E418G | Missense Mutation (SNP) | VAF 15/311 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2
- LEPR | c.1786G>C p.V596L | Missense Mutation (SNP) | VAF 19/388 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2
- LRP4 | c.2950G>C p.E984Q | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.351); called by muse, mutect2
- LRP8 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.262); called by muse, mutect2
- LRRC74B | c.925G>C p.V309L | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.019); called by muse, mutect2
- MACF1 | c.17629C>T p.R5877C (on ENST00000372915; = p.R3919C on NM_012090.5) | Missense Mutation (SNP) | VAF 15/274 reads (5%) | called by muse, mutect2
- MEIS3 | c.*17+3G>A | Splice Region (SNP) | VAF 9/156 reads (6%) | called by muse, mutect2
- MEOX1 | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- MISP | c.346G>T p.G116W | Missense Mutation (SNP) | VAF 44/608 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by muse, mutect2
- MROH1 | c.2830G>T p.A944S | Missense Mutation (SNP) | VAF 20/502 reads (4%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); called by muse, mutect2
- MUC16 | c.38897G>T p.S12966I | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MYBPC3 | c.825C>A p.S275R | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- MYH11 | c.1672G>T p.G558C | Missense Mutation (SNP) | VAF 28/490 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- MYH11 | c.1671G>T p.Q557H | Missense Mutation (SNP) | VAF 28/490 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2
- MYH13 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MYH8 | c.5146G>T p.V1716F | Missense Mutation (SNP) | VAF 52/624 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2
- NAV2 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 16/351 reads (5%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2
- NAV3 | c.4437C>A p.N1479K | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- NCKAP5 | c.3271C>T p.Q1091* | Nonsense Mutation (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- NCOA2 | c.3592C>T p.Q1198* | Nonsense Mutation (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- NLGN4X | c.1384C>G p.Q462E | Missense Mutation (SNP) | VAF 49/379 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NLRP13 | c.1237del p.R413Efs*23 | Frame Shift Del (DEL) | VAF 25/223 reads (11%) | called by mutect2, pindel, varscan2
- NOBOX | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- NUMA1 | c.4945C>T p.R1649* | Nonsense Mutation (SNP) | VAF 14/460 reads (3%) | called by muse, mutect2
- NWD2 | c.3001C>A p.L1001I | Missense Mutation (SNP) | VAF 27/349 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.874); called by muse, mutect2
- OBSCN | c.10378G>A p.E3460K | Missense Mutation (SNP) | VAF 26/625 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.715); called by muse, mutect2
- OR10Q1 | c.116A>G p.Y39C | Missense Mutation (SNP) | VAF 23/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR14I1 | c.721C>A p.P241T | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- OR2L3 | c.149T>A p.L50* | Nonsense Mutation (SNP) | VAF 30/454 reads (7%) | called by muse, mutect2
- OR52L1 | c.440C>A p.P147H | Missense Mutation (SNP) | VAF 18/331 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- OR5H6 | c.307G>C p.A103P (on ENST00000642105; = p.A87P on NM_001005479.2) | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- OTOG | c.916G>T p.D306Y | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OTX2 | c.724G>A p.G242R (on ENST00000408990 / NM_172337.3; = p.G250R on NM_021728.4) | Missense Mutation (SNP) | VAF 36/541 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- P2RY14 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PACS1 | c.281G>T p.R94L | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2
- PCDHA7 | c.2202G>T p.L734F | Missense Mutation (SNP) | VAF 21/233 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); called by muse, mutect2
- PCDHGB6 | c.2339T>G p.V780G | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- PCYT2 | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); called by muse, mutect2
- PKD1L1 | c.7800C>A p.D2600E | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PLEC | c.5458G>T p.A1820S (on ENST00000322810 / NM_201380.4; = p.A1710S on NM_000445.5) | Missense Mutation (SNP) | VAF 18/463 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- PLEKHG4 | c.2759A>G p.N920S | Missense Mutation (SNP) | VAF 22/595 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2
- PPFIA4 | c.2223G>T p.Q741H (on ENST00000447715; = p.Q742H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/380 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- PRKDC | c.1737G>T p.L579F | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTCH1 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 17/447 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- PTCH1 | c.640G>T p.G214C | Missense Mutation (SNP) | VAF 16/445 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.662); called by muse, mutect2
- PTCH2 | c.2956C>A p.P986T | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); called by muse, mutect2
- PTPRN | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2
- REV3L | c.423A>T p.Q141H | Missense Mutation (SNP) | VAF 22/311 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- RIMS2 | c.1344G>C p.L448F (on ENST00000666250 / NM_001348490.2; = p.L256F on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/285 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.732); called by muse, mutect2
- RIPK1 | c.1804G>T p.A602S | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2
- RIT2 | c.71T>C p.V24A | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- RYR1 | c.3177C>T p.P1059= | Splice Region (SNP) | VAF 46/313 reads (15%) | called by muse, mutect2, varscan2
- SCNN1G | c.904A>T p.S302C | Missense Mutation (SNP) | VAF 14/337 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- SEH1L | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SEMG2 | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.831); called by muse, mutect2
- SEPTIN3 | c.668G>T p.R223M | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SF3B1 | c.2199G>T p.K733N | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.14); called by muse, mutect2
- SLC13A1 | c.770C>A p.T257N | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SLC22A12 | c.949C>A p.P317T | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2
- SLC2A7 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 17/291 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2
- SLC36A3 | c.842A>C p.Q281P | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2
- SLC36A3 | c.841C>G p.Q281E | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.017); called by muse, mutect2
- SLC4A10 | c.1149G>T p.Q383H (on ENST00000446997 / NM_001354461.2; = p.Q353H on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2
- SLC6A18 | c.580G>C p.V194L | Missense Mutation (SNP) | VAF 38/385 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- SMARCAL1 | c.2071-2A>G p.X691_splice | Splice Site (SNP) | VAF 20/454 reads (4%) | called by muse, mutect2
- SOWAHA | c.844T>C p.S282P | Missense Mutation (SNP) | VAF 19/239 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2
- SP4 | c.1354A>T p.T452S | Missense Mutation (SNP) | VAF 37/334 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- SPAG17 | c.4847C>A p.T1616N | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- SPTA1 | c.376C>A p.H126N | Missense Mutation (SNP) | VAF 32/467 reads (7%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.543); called by muse, mutect2
- SREBF2 | c.370A>T p.T124S | Missense Mutation (SNP) | VAF 41/663 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0.01); called by muse, mutect2
- SSX3 | c.155A>T p.K52M | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAS2R50 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- TBCD | c.346A>G p.K116E | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TEK | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 20/498 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.125); called by muse, mutect2
- TIPARP | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 30/436 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.053); called by muse, mutect2
- TMEM121 | c.396C>A p.D132E | Missense Mutation (SNP) | VAF 41/422 reads (10%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.978); called by muse, mutect2
- TMEM121B | c.1694C>G p.A565G | Missense Mutation (SNP) | VAF 58/574 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2
- TRGV3 | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 28/532 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.121); called by muse, mutect2
- TRIM15 | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 48/419 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- TRIM31 | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 22/562 reads (4%) | called by muse, mutect2
- TRIM48 | c.401C>A p.S134Y | Missense Mutation (SNP) | VAF 36/628 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRPC3 | c.514C>A p.L172M (on ENST00000379645 / NM_001366479.2; = p.L99M on NM_003305.2) | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.951); called by muse, mutect2
- TTLL6 | c.2428G>A p.G810R (on ENST00000393382 / NM_001130918.3; = p.G503R on NM_173623.3) | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TUBE1 | c.1081A>G p.R361G | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.445); called by muse, mutect2
- UGT3A2 | c.974A>T p.Q325L | Missense Mutation (SNP) | VAF 38/569 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- USH2A | c.3703A>G p.T1235A | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2
- UTP6 | c.1535G>T p.R512M | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.079); called by muse, mutect2
- UTP6 | c.1534A>T p.R512W | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2
- VCAM1 | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 14/258 reads (5%) | called by muse, mutect2
- VEGFC | c.1146-1G>T p.X382_splice | Splice Site (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- VPS13B | c.7257A>C p.K2419N | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2
- WDR87 | c.7736A>T p.Q2579L | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ZBTB46 | c.329G>T p.S110I | Missense Mutation (SNP) | VAF 22/339 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZFHX4 | c.4930A>T p.S1644C | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ZFHX4 | c.5626G>T p.G1876C | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.303); called by muse, mutect2
- ZFHX4 | c.7599G>T p.M2533I | Missense Mutation (SNP) | VAF 8/185 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.031); called by muse, mutect2
- ZFR2 | c.691C>A p.Q231K | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2
- ZNF146 | c.82A>T p.K28* | Nonsense Mutation (SNP) | VAF 10/211 reads (5%) | called by muse, mutect2
- ZNF274 | c.1051A>T p.S351C (on ENST00000610905; = p.S246C on NM_016324.3) | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- ZNF274 | c.1312C>T p.Q438* (on ENST00000610905; = p.Q333* on NM_016324.3) | Nonsense Mutation (SNP) | VAF 47/489 reads (10%) | called by muse, mutect2, varscan2
- ZNF277 | c.801+3A>T | Splice Region (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- ZNF320 | c.175T>C p.S59P | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- ZNF441 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 27/291 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF717 | c.1331C>A p.T444K | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.151); called by muse, varscan2
- ZNF99 | c.130+1G>C p.X44_splice | Splice Site (SNP) | VAF 8/227 reads (4%) | called by muse, mutect2
- ZNRF3 | c.1212G>T p.E404D (on ENST00000544604 / NM_001206998.2; = p.E304D on NM_032173.3) | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.079); called by muse, mutect2
- ADAMTS18 | c.1665C>T p.T555= | Silent (SNP) | VAF 19/390 reads (5%) | called by muse, mutect2
- ADGRG7 | c.2358A>G p.T786= | Silent (SNP) | VAF 11/182 reads (6%) | called by muse, mutect2
- AFF2 | c.2829C>T p.I943= | Silent (SNP) | VAF 28/253 reads (11%) | catalogued as rs1557288251; called by muse, mutect2, varscan2
- AGFG1 | c.102G>A p.Q34= | Silent (SNP) | VAF 22/456 reads (5%) | called by muse, mutect2
- ALDH1A1 | c.222A>T p.G74= | Silent (SNP) | VAF 14/252 reads (6%) | called by muse, mutect2
- ANO3 | c.859C>A p.R287= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as COSV56788795; called by muse, mutect2
- AP5Z1 | c.1980G>T p.R660= | Silent (SNP) | VAF 23/344 reads (7%) | called by muse, mutect2
- ARSF | c.1200T>C p.P400= | Silent (SNP) | VAF 11/161 reads (7%) | called by muse, mutect2
- ATF6B | c.1419T>C p.S473= | Silent (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- BHLHA15 | c.222C>A p.I74= | Silent (SNP) | VAF 30/519 reads (6%) | catalogued as rs551056455; called by muse, mutect2
- C1QA | c.492G>A p.Q164= | Silent (SNP) | VAF 44/594 reads (7%) | catalogued as rs1431414268; called by muse, mutect2
- C7orf25 | c.342T>C p.H114= | Silent (SNP) | VAF 13/192 reads (7%) | called by muse, mutect2
- CARMIL2 | c.1716G>T p.R572= | Silent (SNP) | VAF 7/162 reads (4%) | called by muse, mutect2
- CARMIL3 | c.1095C>T p.A365= | Silent (SNP) | VAF 15/372 reads (4%) | called by muse, mutect2
- CCM2L | c.388C>T p.L130= | Silent (SNP) | VAF 18/278 reads (6%) | catalogued as COSV52953059; called by muse, mutect2
- CDH18 | c.1701C>A p.P567= | Silent (SNP) | VAF 16/294 reads (5%) | catalogued as COSV56946592, COSV56954100; called by muse, mutect2
- CDSN | c.936C>A p.T312= | Silent (SNP) | VAF 110/687 reads (16%) | called by muse, mutect2, varscan2
- CEACAM18 | c.915G>T p.L305= | Silent (SNP) | VAF 16/422 reads (4%) | catalogued as rs1392657889, COSV67282731; called by muse, mutect2
- CHAC1 | c.450T>A p.P150= | Silent (SNP) | VAF 14/359 reads (4%) | called by muse, mutect2
- CNBD1 | c.478C>T p.L160= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as COSV72976180; called by muse, mutect2
- CPO | c.42G>T p.L14= | Silent (SNP) | VAF 15/238 reads (6%) | called by muse, mutect2
- CYFIP2 | c.3256C>T p.L1086= (on ENST00000616178 / NM_001291722.2; = p.L1061= on NM_014376.4) | Silent (SNP) | VAF 12/365 reads (3%) | called by muse, mutect2
- DMD | c.8488C>A p.R2830= | Silent (SNP) | VAF 12/188 reads (6%) | catalogued as COSV58947733; called by muse, mutect2
- DNAH10 | c.3903T>A p.A1301= (on ENST00000409039; = p.A1240= on NM_207437.3) | Silent (SNP) | VAF 13/308 reads (4%) | called by muse, mutect2
- DSG1 | c.1296G>T p.L432= | Silent (SNP) | VAF 32/374 reads (9%) | called by muse, mutect2
- EGFLAM | c.588C>A p.I196= | Silent (SNP) | VAF 11/189 reads (6%) | catalogued as COSV59308814; called by muse, mutect2
- EPHA7 | c.1485C>A p.T495= | Silent (SNP) | VAF 12/86 reads (14%) | called by muse, varscan2
- ESRRB | c.441C>A p.I147= | Silent (SNP) | VAF 34/626 reads (5%) | called by muse, mutect2
- GBP5 | c.1434G>A p.Q478= | Silent (SNP) | VAF 12/224 reads (5%) | catalogued as COSV58594120; called by muse, mutect2
- GPR37 | c.1491G>T p.L497= | Silent (SNP) | VAF 18/156 reads (12%) | called by muse, mutect2, varscan2
- HOXB5 | c.42A>T p.P14= | Silent (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- KCNK15 | c.717C>T p.L239= | Silent (SNP) | VAF 14/410 reads (3%) | catalogued as COSV65720781; called by muse, mutect2
- KLHL30 | c.426G>T p.G142= | Silent (SNP) | VAF 12/231 reads (5%) | called by muse, mutect2
- KPRP | c.1104T>A p.P368= | Silent (SNP) | VAF 14/416 reads (3%) | called by muse, mutect2
- LAMC3 | c.333C>A p.G111= | Silent (SNP) | VAF 24/658 reads (4%) | called by muse, mutect2
- MAGEE2 | c.942G>A p.K314= | Silent (SNP) | VAF 15/202 reads (7%) | catalogued as COSV64898038; called by muse, mutect2
- MET | c.156C>T p.I52= | Silent (SNP) | VAF 23/337 reads (7%) | called by muse, mutect2
- MUC5B | c.4368C>A p.T1456= | Silent (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- MYO9B | c.2067G>T p.R689= | Silent (SNP) | VAF 32/506 reads (6%) | catalogued as COSV101261651; called by muse, mutect2
- NIPAL1 | c.1182A>T p.S394= | Silent (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- NPHS2 | c.882T>A p.A294= | Silent (SNP) | VAF 16/190 reads (8%) | called by muse, mutect2
- OR52N1 | c.180T>G p.P60= | Silent (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- OR8H2 | c.201G>A p.L67= | Silent (SNP) | VAF 8/212 reads (4%) | called by muse, mutect2
- OTOF | c.1320A>G p.V440= | Silent (SNP) | VAF 27/330 reads (8%) | called by muse, mutect2
- PIK3CG | c.1585C>T p.L529= | Silent (SNP) | VAF 22/164 reads (13%) | catalogued as rs1449605501; called by muse, mutect2, varscan2
- PLCB4 | c.2943G>A p.K981= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as COSV99595487; called by muse, mutect2
- PSG1 | c.1050C>A p.L350= | Silent (SNP) | VAF 12/270 reads (4%) | called by muse, mutect2
- RAB3IL1 | c.774C>T p.F258= | Silent (SNP) | VAF 18/370 reads (5%) | called by muse, mutect2
- REG3G | c.414C>A p.S138= | Silent (SNP) | VAF 13/282 reads (5%) | called by muse, mutect2
- RIPOR3 | c.2835A>T p.I945= | Silent (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- RYR2 | c.8109A>T p.P2703= | Silent (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- SCARA5 | c.1212C>A p.G404= | Silent (SNP) | VAF 21/343 reads (6%) | called by muse, mutect2
- SLC13A5 | c.918C>T p.Y306= | Silent (SNP) | VAF 16/359 reads (4%) | catalogued as rs1249247580; called by muse, mutect2
- SLC26A1 | c.750G>A p.L250= | Silent (SNP) | VAF 20/342 reads (6%) | catalogued as rs977691859; called by muse, mutect2
- SLC27A3 | c.240G>T p.V80= | Silent (SNP) | VAF 18/163 reads (11%) | called by muse, mutect2, varscan2
- SLC30A6 | c.1254A>T p.T418= | Silent (SNP) | VAF 13/229 reads (6%) | called by muse, mutect2
- SPATA31D1 | c.3438C>T p.T1146= | Silent (SNP) | VAF 12/216 reads (6%) | catalogued as COSV61201579; called by muse, mutect2
- SYNE3 | c.2601A>T p.P867= | Silent (SNP) | VAF 16/268 reads (6%) | called by muse, mutect2
- SYNGR1 | c.262C>T p.L88= | Silent (SNP) | VAF 15/344 reads (4%) | called by muse, mutect2
- TBX19 | c.465G>C p.G155= | Silent (SNP) | VAF 33/418 reads (8%) | catalogued as rs778916517; called by muse, mutect2
- TMPRSS15 | c.1806A>G p.V602= | Silent (SNP) | VAF 22/338 reads (7%) | catalogued as rs750681969; called by muse, mutect2
- TRPM5 | c.2535C>T p.F845= | Silent (SNP) | VAF 14/358 reads (4%) | called by muse, mutect2
- TUBE1 | c.1080T>A p.R360= | Silent (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- UMOD | c.297C>T p.R99= | Silent (SNP) | VAF 45/431 reads (10%) | catalogued as COSV56776636; called by muse, mutect2, varscan2
- UNC5C | c.714C>A p.T238= | Silent (SNP) | VAF 23/230 reads (10%) | called by muse, mutect2
- ZBTB48 | c.88C>T p.L30= | Silent (SNP) | VAF 12/318 reads (4%) | catalogued as COSV100039745; called by muse, mutect2
- ZDBF2 | c.693A>T p.P231= | Silent (SNP) | VAF 11/255 reads (4%) | called by muse, mutect2
- ZNF263 | c.144C>G p.R48= | Silent (SNP) | VAF 14/268 reads (5%) | catalogued as rs1259456143; called by muse, mutect2
- ABI3BP | c.1063+15T>C | Intron (SNP) | VAF 11/86 reads (13%) | catalogued as COSV52527351; called by muse, mutect2, varscan2
- AC092377.1 | chr16:85357560 G>T | 5'Flank (SNP) | VAF 8/179 reads (4%) | called by muse, mutect2
- AC114741.1 | n.158T>C | RNA (SNP) | VAF 20/340 reads (6%) | called by muse, mutect2
- AL136982.4 | n.62G>C | RNA (SNP) | VAF 16/478 reads (3%) | catalogued as rs1200904052; called by muse, mutect2
- AL353804.4 | chrX:73823954 A>T | 5'Flank (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- ALOXE3 | c.-313-91C>A | Intron (SNP) | VAF 35/329 reads (11%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505344 T>C | 5'Flank (SNP) | VAF 9/185 reads (5%) | called by muse, mutect2
- ARMC6 | c.29+3353C>A | Intron (SNP) | VAF 13/177 reads (7%) | called by muse, mutect2
- CCDC187 | c.*2734C>A | 3'UTR (SNP) | VAF 9/111 reads (8%) | called by muse, mutect2
- CDYL | c.186+38306G>T | Intron (SNP) | VAF 11/285 reads (4%) | called by muse, mutect2
- CHODL | c.79+620G>A | Intron (SNP) | VAF 20/192 reads (10%) | called by muse, mutect2
- CHRAC1 | c.147+318C>T | Intron (SNP) | VAF 8/161 reads (5%) | called by muse, mutect2
- COL1A1 | chr17:50180868 C>A | 3'Flank (SNP) | VAF 11/120 reads (9%) | called by muse, mutect2
- CRYBG2 | c.4038+101T>A | Intron (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- CTAGE11P | n.317G>T | RNA (SNP) | VAF 32/826 reads (4%) | called by muse, mutect2
- CYBA | c.287+168C>T | Intron (SNP) | VAF 12/314 reads (4%) | called by muse, mutect2
- ERVV-1 | chr19:53009653 G>T | 5'Flank (SNP) | VAF 19/402 reads (5%) | called by muse, mutect2
- FER1L4 | n.2907A>C | RNA (SNP) | VAF 16/220 reads (7%) | called by muse, mutect2
- GRTP1 | c.921+29C>A | Intron (SNP) | VAF 10/223 reads (4%) | called by muse, mutect2
- ICOS | c.*10C>T | 3'UTR (SNP) | VAF 15/480 reads (3%) | catalogued as COSV100320331; called by muse, mutect2
- IGF2BP2 | c.240-23906G>T | Intron (SNP) | VAF 16/330 reads (5%) | called by muse, mutect2
- IGFN1 | c.1241+28A>G | Intron (SNP) | VAF 16/204 reads (8%) | catalogued as rs1292020345; called by muse, mutect2
- ITGA4 | c.*1892C>T | 3'UTR (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- KCNMB1 | c.306+39C>A | Intron (SNP) | VAF 35/346 reads (10%) | catalogued as rs538353830; called by muse, mutect2, varscan2
- LAMP2 | c.1093+2502G>T | Intron (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- LRRC63 | chr13:46270370 C>A | 3'Flank (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
- MIR7-3 | chr19:4772207 C>A | 3'Flank (SNP) | VAF 10/288 reads (3%) | called by muse, mutect2
- MPP1 | c.784+133C>T | Intron (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- MYH11 | c.633+138G>T | Intron (SNP) | VAF 8/232 reads (3%) | called by muse, mutect2
- MYO7B | c.6250-101C>A | Intron (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- NCL | chr2:231452722 C>T | 3'Flank (SNP) | VAF 16/173 reads (9%) | called by muse, mutect2
- NIPAL2 | c.*65G>T | 3'UTR (SNP) | VAF 19/138 reads (14%) | called by muse, mutect2, varscan2
- OCLNP1 | n.79G>A | RNA (SNP) | VAF 13/326 reads (4%) | called by muse, mutect2
- OR7E5P | n.565C>A | RNA (SNP) | VAF 26/404 reads (6%) | catalogued as rs560615671; called by muse, mutect2
- PDCD10 | c.-9G>T | 5'UTR (SNP) | VAF 11/211 reads (5%) | called by muse, mutect2
- PDXDC2P-NPIPB14P | n.1745C>A | RNA (SNP) | VAF 40/821 reads (5%) | called by muse, mutect2
- PLG | c.547+29A>T | Intron (SNP) | VAF 24/292 reads (8%) | called by muse, mutect2
- PMP22 | c.78+24C>T | Intron (SNP) | VAF 28/510 reads (5%) | catalogued as rs757616821; called by muse, mutect2
- PPDPFL | c.-20G>T | 5'UTR (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- PRDM11 | c.657-6698G>T | Intron (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- RAMP2 | chr17:42761063 G>A | 5'Flank (SNP) | VAF 5/40 reads (13%) | catalogued as rs968449153; called by muse, mutect2, varscan2
- SH2D6 | n.470C>T | RNA (SNP) | VAF 9/218 reads (4%) | called by muse, mutect2
- SLIT3 | c.4337-48T>A | Intron (SNP) | VAF 14/378 reads (4%) | called by muse, mutect2
- TG | c.*40C>A | 3'UTR (SNP) | VAF 17/416 reads (4%) | called by muse, mutect2
- TWF1 | c.25+320C>T | Intron (SNP) | VAF 15/289 reads (5%) | called by muse, mutect2
- TWF1 | c.-50G>T | 5'UTR (SNP) | VAF 21/168 reads (13%) | called by muse, mutect2, varscan2
- VCP | c.1696-23G>A | Intron (SNP) | VAF 11/185 reads (6%) | catalogued as rs910037459; called by muse, mutect2
